Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6Z0, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6Z0-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

ICD-O-3 8811/3
Fibromyosarcoma
Site R Thigh NOS C49.2
JW 8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with right thigh high grade sarcoma.

Specimens Submitted:

1: SP: Excision sarcoma, right medial thigh

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT MEDIAL THIGH MASS, EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA DIFFUSELY INFILTRATING SKELETAL MUSCLE AND ADIPOSE TISSUE.
- GROSS TUMOR MEASUREMENT: 4.4 X 2.8 X 2.5 CM.
- TUMOR EXTENDS TO THE MULTIPLE INKED UNDESIGNATED MARGINS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "excision sarcoma right medial thigh" and consists of a soft tissue excisional specimen with an elliptical segment of skin attached. Entire specimen measures 12.5 x 6.5 x 3.5 cm in greatest dimensions. The skin ellipse measures 0.5 x 2.5 cm in greatest dimensions. The specimen is not oriented. The skin surface is white and noticeable for an old, well-healed linear surgical scar which measures 2.5 cm in length and is 0.2 cm from the closest skin margin. Surgical margins are inked in black. Sectioning of the specimen reveals a 4.4 x 2.8 x 2.5 cm ill-defined soft tissue tumor in the subcutaneous tissue of the specimen. Grossly, the tumor is 0.1 cm from the closest inked surgical margin. Sectioning through the specimen reveals a soft, lobulated, fairly homogenous, light yellow cut surface with no hemorrhage or necrosis identified. Samples of the soft tissue mass are submitted for TPS. Gross

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
photos are taken. Representative sections are submitted.

Summary of sections:
TM tumor in relation to inked surgical margin, perpendicular
TMS tumor in relation to adjacent skeletal muscle
SKIN representative section of skin at the scar
T additional sections of the tumor

Summary of Sections:
Part 1: SP: Excision sarcoma, right medial thigh

Block	Sect.	Site	PCs
1		SKIN	1
2		T	2
4		TM	4
2		TMS	2

** End of Report **

Criteria	hu 7/27/15	Yes	No

Source: NCI Genomic Data Commons file 5062268e-59e5-4e84-b5ef-7b7e8ed4512a (TCGA-DX-A6Z0.6E54D4E1-23E5-4E1D-979A-19909E30AF48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).